Somatic mutation profile of tumor specimen MP2PRT-PARJMR-TMP1-A (aliquot MP2PRT-PARJMR-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARJMR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,903 days).
Specimen MP2PRT-PARJMR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4385aee-0ca8-4c8e-8b77-9c2098907136.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARJMR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARJMR-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa3762b7-91e3-43f3-9398-7e75dd5fe29f

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH2 | c.1128+1810C>T | Intron (SNP) | VAF 262/555 reads (47%) | catalogued as rs972201049, CM088338; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 31/450 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 76/266 reads (29%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- ADAD1 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as rs746909373; called by muse, mutect2, varscan2
- ARNT | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 175/546 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62230780; called by muse, mutect2, varscan2
- ARSF | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 183/454 reads (40%) | catalogued as rs200082842, COSV63840843; called by muse, mutect2, varscan2
- C5orf34 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145766724; called by muse, mutect2, varscan2
- DNAH9 | c.8146C>T p.R2716W | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs756890065, COSV52377060; called by muse, mutect2, varscan2
- DNM2 | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 45/458 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100118329; called by muse, mutect2
- DSCAML1 | c.4766G>A p.R1589Q (on ENST00000321322; = p.R1529Q on NM_020693.4) | Missense Mutation (SNP) | VAF 239/582 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs547034218; called by muse, varscan2
- EPB41L5 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 64/303 reads (21%) | catalogued as rs760987295; called by muse, mutect2, varscan2
- GALNTL6 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72494153; called by muse, mutect2
- GATA6 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 141/625 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1358127161; called by muse, mutect2, varscan2
- GOLGA6L10 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 58/1084 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs1474801310; called by muse, mutect2
- JPH2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs1339089624, COSV100881569; called by muse, mutect2, varscan2
- NARS1 | c.594T>G p.H198Q | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV56876953; called by mutect2, varscan2
- OR52E8 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66210619; called by muse, mutect2, varscan2
- RELN | c.8684G>A p.R2895H | Missense Mutation (SNP) | VAF 112/257 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs1399157725; called by muse, mutect2, varscan2
- RUNX1 | c.511G>A p.D171N (on ENST00000344691 / NM_001001890.3; = p.D198N on NM_001754.5) | Missense Mutation (SNP) | VAF 48/540 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as CM013280, CM1515470, COSV55868860, COSV55892672; called by muse, mutect2
- TRAPPC11 | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 19/538 reads (4%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.519); catalogued as rs951875459; called by muse, mutect2
- ZNF521 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 203/429 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.105); catalogued as rs116142901; called by muse, mutect2, varscan2
- ADGRG4 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 149/404 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CENPE | c.1973T>C p.L658P | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- CRP | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 111/491 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EIF4A3 | c.26C>A p.T9N | Missense Mutation (SNP) | VAF 214/459 reads (47%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT1 | c.2489A>G p.E830G | Missense Mutation (SNP) | VAF 23/522 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.329); called by muse, mutect2
- HOXD1 | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 290/643 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- HSP90AA1 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- KCNA1 | c.982C>A p.L328M | Missense Mutation (SNP) | VAF 213/500 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MCAM | c.1213T>A p.Y405N | Missense Mutation (SNP) | VAF 240/534 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOP56 | c.1572_1573insGG p.T525Gfs*? | Frame Shift Ins (INS) | VAF 158/486 reads (33%) | called by mutect2, pindel, varscan2
- NRXN2 | c.5131T>A p.Y1711N | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51V1 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 75/362 reads (21%) | called by muse, mutect2, varscan2
- PAK1IP1 | c.496A>C p.N166H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PCDH10 | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 338/749 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POP4 | c.534del p.K179Sfs*2 | Frame Shift Del (DEL) | VAF 56/151 reads (37%) | called by mutect2, pindel, varscan2
- POT1 | c.9+1G>C p.X3_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- PRKAA2 | c.1499C>A p.S500* | Nonsense Mutation (SNP) | VAF 75/396 reads (19%) | called by muse, mutect2, varscan2
- PRPF40A | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 117/327 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UBE4B | c.1261T>A p.C421S (on ENST00000343090 / NM_001105562.3; = p.C292S on NM_006048.5) | Missense Mutation (SNP) | VAF 172/371 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- USP38 | c.2558C>A p.S853Y | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS53 | c.1067G>A p.G356E (on ENST00000571805 / NM_001366253.2; = p.G327E on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/413 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- ZC4H2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 272/604 reads (45%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.802); called by muse, mutect2
- ZNF865 | c.2689G>T p.V897L | Missense Mutation (SNP) | VAF 392/874 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CDH6 | c.1959A>G p.R653= | Silent (SNP) | VAF 214/447 reads (48%) | catalogued as COSV54069510; called by muse, mutect2, varscan2
- CNNM3 | c.1533C>T p.F511= | Silent (SNP) | VAF 26/310 reads (8%) | catalogued as rs776286499; called by muse, mutect2
- CYP8B1 | c.726G>C p.V242= | Silent (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
- FBXL12 | c.775C>T p.L259= | Silent (SNP) | VAF 225/517 reads (44%) | catalogued as COSV99928115; called by muse, mutect2, varscan2
- GBP7 | c.978C>T p.A326= | Silent (SNP) | VAF 160/426 reads (38%) | catalogued as rs768372837; called by muse, mutect2, varscan2
- GFY | c.1110G>T p.L370= | Silent (SNP) | VAF 74/605 reads (12%) | called by muse, varscan2
- GJA9 | c.522A>G p.G174= | Silent (SNP) | VAF 161/365 reads (44%) | called by muse, mutect2, varscan2
- IRX1 | c.912C>T p.G304= | Silent (SNP) | VAF 229/943 reads (24%) | called by muse, mutect2, varscan2
- ITIH4 | c.639C>T p.I213= | Silent (SNP) | VAF 96/227 reads (42%) | called by muse, mutect2, varscan2
- LRRN1 | c.495C>A p.G165= | Silent (SNP) | VAF 49/432 reads (11%) | called by muse, mutect2, varscan2
- PCDH11X | c.2058A>G p.L686= | Silent (SNP) | VAF 85/472 reads (18%) | called by muse, mutect2, varscan2
- RAB32 | c.27C>T p.P9= | Silent (SNP) | VAF 142/296 reads (48%) | catalogued as rs750167796; called by muse, mutect2, varscan2
- SLC5A9 | c.1335C>A p.I445= | Silent (SNP) | VAF 136/335 reads (41%) | catalogued as rs1468395531, COSV52584217; called by muse, mutect2, varscan2
- TNRC18 | c.6528C>T p.A2176= | Silent (SNP) | VAF 42/253 reads (17%) | catalogued as rs766645034; called by muse, mutect2, varscan2
